CCDI case PBCPJV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/989c976a-41c6-4115-b898-16f4dc2448ba

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 16.4 years (5,988 days).

Biospecimens (3 samples)
- Sample 0DWYUS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWYVA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWYWK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
